CCDI case PBCTEH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/28b202e7-ed83-4a2e-9980-c2248b04f187

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,751 days).

Biospecimens (3 samples)
- Sample 0DYZVZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYZW6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYZW9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
